MMRF case MMRF_1082 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e41ed7e6-7832-41a9-b816-23986df22808

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Dead; Days to death: 830 days (2.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 47.5 years (17,339 days); ISS stage: II; Days to last known disease status: 830 days (2.3 years); Days to last follow up: 830 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 274 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 288 days; Days to treatment end: 326 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 371 days (1.0 years); Days to treatment end: 372 days (1.0 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 373 days (1.0 years); Days to treatment end: 373 days (1.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 500 days (1.4 years); Days to treatment end: 582 days (1.6 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 588 days (1.6 years); Days to treatment end: 680 days (1.9 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 661 days (1.8 years); Days to treatment end: 750 days (2.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 830.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 1): M Protein 8.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.998 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 113 mg/dL; Immunoglobulin G 120 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 81 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 1.95 mmol/L; Albumin 25 g/L; Total Protein 14.1 g/dL; Glucose 4.02 mmol/L.
- Day 52 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.43 mg/dL; Immunoglobulin G 19 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 282 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 6.16 mmol/L.
- Day 157 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 6.67 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.61 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 17.9 ×10⁹/L; Absolute Neutrophil 16 ×10⁹/L; Platelets 297 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 14.4 mmol/L.
- Day 255 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.63 mg/dL; Hemoglobin 7.81 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 274 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 4.9 mmol/L.
- Day 359 (ECOG 1): M Protein 0.4 g/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.79 µg/mL; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 13.2 ×10⁹/L; Absolute Neutrophil 8.93 ×10⁹/L; Platelets 316 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.53 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 5.12 mmol/L.
- Day 422 (ECOG 0): Hemoglobin 7.13 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 4.62 mmol/L.
- Day 507 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Beta 2 Microglobulin 1.83 µg/mL; Hemoglobin 7.44 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 4.73 mmol/L.
- Day 598 (ECOG 0): M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 49.9 mg/dL; Immunoglobulin G 25 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 5.04 µg/mL; Hemoglobin 4.65 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 38 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.58 mmol/L; Albumin 33 g/L; Total Protein 12 g/dL; Glucose 4.35 mmol/L.
- Day 694 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.42 mg/dL; Immunoglobulin G 28.1 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 37 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7.8 g/dL; Glucose 4.73 mmol/L.
- Day 801 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.9 mg/dL; Immunoglobulin G 31.1 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 15.1 ×10⁹/L; Absolute Neutrophil 12 ×10⁹/L; Platelets 58 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 8.5 g/dL; Glucose 8.64 mmol/L.

Other clinical attributes
- Day -14: Weight: 114 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1082_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_1082_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
